Somatic mutation profile of tumor specimen MMRF_2316_1_BM_CD138pos (aliquot MMRF_2316_1_BM_CD138pos_T1_KHS5U_L09524) from MMRF case MMRF_2316, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.4 years (23,530 days).
Specimen MMRF_2316_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79f0e621-f4e8-45fd-ae48-13d2657c8be5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2316_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2316_1_PB_Whole_C3_KHS5U_L09525; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a94f56c4-69f3-44e8-81f8-a6666eb891a2

The open-access MAF lists 50 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 10, Intron 6, Silent 5, Nonsense Mutation 3, 5'UTR 3, 3'Flank 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDH20 | c.2234T>C p.L745P | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364728639; called by muse, mutect2, varscan2
- COL12A1 | c.7151A>G p.K2384R | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1232482250, COSV59402540; called by muse, mutect2, varscan2
- IGLV3-10 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 76/81 reads (94%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as rs1065463; called by muse, mutect2
- IGLV4-60 | c.355A>G p.N119D | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as rs372291894; called by muse, varscan2
- KLHDC7A | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs776362096, COSV68769484; called by muse, mutect2, varscan2
- NINL | c.2455G>A p.G819R | Missense Mutation (SNP) | VAF 114/220 reads (52%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs372862049, COSV54002148; called by muse, mutect2, varscan2
- PXDN | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs749632473; called by muse, mutect2, varscan2
- RYR1 | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs558969466, COSV62102938; called by muse, mutect2, varscan2
- SIGLEC9 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as rs1568613901, COSV51587118; called by muse, mutect2
- ANKRD50 | c.108C>G p.C36W | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- COL4A1 | c.2125C>A p.P709T | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.45); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DYNC1I1 | c.1778T>C p.V593A | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- DYNC2H1 | c.11160dup p.E3721* | Frame Shift Ins (INS) | VAF 41/193 reads (21%) | called by mutect2, pindel, varscan2
- FSHR | c.1597T>C p.S533P | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- MGLL | c.469A>G p.T157A (on ENST00000398104 / NM_001003794.2; = p.T167A on NM_007283.6) | Missense Mutation (SNP) | VAF 105/298 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MYPN | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.4874T>A p.L1625* | Nonsense Mutation (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- POLB | c.107A>C p.Y36S | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.12); called by muse, mutect2
- SLC4A2 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 55/120 reads (46%) | PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- WIPI2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZNF567 | c.1324A>G p.T442A (on ENST00000536254 / NM_001322913.1; = p.T411A on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRB2 | c.2487G>A p.P829= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1312686351; called by muse, mutect2
- ASIC4 | c.360C>T p.I120= | Silent (SNP) | VAF 17/242 reads (7%) | catalogued as COSV61731209, COSV61732009; called by muse, mutect2
- DICER1 | c.4029T>G p.L1343= | Silent (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- NKTR | c.4110G>T p.R1370= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- PEAR1 | c.963C>T p.C321= | Silent (SNP) | VAF 102/210 reads (49%) | called by muse, mutect2, varscan2
- AC012485.1 | n.243A>T | RNA (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- ACACB | c.6788-789C>G | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, varscan2
- ACTA1 | c.*235A>G | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- ANGEL2 | c.*1489G>T | 3'UTR (SNP) | VAF 40/72 reads (56%) | called by muse, mutect2, varscan2
- C12orf77 | n.612+67G>T | Intron (SNP) | VAF 78/174 reads (45%) | called by muse, varscan2
- C12orf77 | n.612+20A>C | Intron (SNP) | VAF 120/250 reads (48%) | called by muse, varscan2
- CDH11 | c.-321T>A | 5'UTR (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65884305 del A | 3'Flank (DEL) | VAF 47/133 reads (35%) | called by mutect2, pindel, varscan2
- CHRAC1 | c.*1549G>C | 3'UTR (SNP) | VAF 57/146 reads (39%) | called by muse, mutect2, varscan2
- EFNA5 | c.418+194T>C | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- LAPTM4B | c.-536T>C | 5'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- MAGI2 | c.538+51C>T | Intron (SNP) | VAF 37/92 reads (40%) | catalogued as rs1460693653; called by muse, mutect2, varscan2
- MIB1 | c.*1470T>A | 3'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- NECAP1 | c.*1465A>G | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- PRRX1 | c.*1833G>C | 3'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82978679 A>G | 3'Flank (SNP) | VAF 103/143 reads (72%) | called by muse, mutect2, varscan2
- RHOU | c.*2683_*2684del | 3'UTR (DEL) | VAF 16/53 reads (30%) | catalogued as rs1558088919; called by mutect2, pindel, varscan2
- SEPTIN5 | c.-10G>A | 5'UTR (SNP) | VAF 17/23 reads (74%) | called by muse, mutect2, varscan2
- TM9SF4 | c.*536G>A | 3'UTR (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- WNT5A | c.*1284T>G | 3'UTR (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- XKR6 | c.764+90885C>T | Intron (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- ZXDA | c.*732T>A | 3'UTR (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
